Somatic mutation profile of tumor specimen 0DECYM from CCDI case PBBPNE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 14.7 years (5,373 days).
Specimen 0DECYM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e5405bf-2f7f-47e6-a3ce-ee7a9290d949.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DECX0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91c5084e-3afd-460f-bb1a-2b4f3934795b

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NIPBL | c.7814A>G p.K2605R | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs754514853; called by muse, mutect2, varscan2
- SLC10A1 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 29/465 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs148905100; ClinVar: uncertain significance; called by muse, mutect2
- SOX6 | c.1980A>T p.K660N (on ENST00000528429 / NM_001145819.2; = p.K633N on NM_017508.3) | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIF17 | c.2364G>A p.S788= | Silent (SNP) | VAF 23/229 reads (10%) | catalogued as rs368058864; called by muse, mutect2, varscan2
